Somatic mutation profile of cancer-model specimen HCM-BROD-0223-C43-85M (Adherent Cell Line, passage 8; aliquot HCM-BROD-0223-C43-85M-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-BROD-0223-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.2 years (26,743 days).
Specimen HCM-BROD-0223-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e98171b-694e-4056-a70c-89e21ab079b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0223-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0223-C43-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ee5c272-1717-45a5-a80d-add0f3dbd271

The open-access MAF lists 2,680 somatic variants for this specimen: 1,560 protein-altering or splice-affecting, 784 silent, 336 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,398, Silent 784, Intron 145, Nonsense Mutation 88, RNA 61, 3'UTR 51, 5'Flank 33, Splice Region 32, 5'UTR 28, Splice Site 20, 3'Flank 17, Frame Shift Del 15.

Variants (750 of 2,680; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.9175C>T p.R3059C | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs146377316, CM127717, COSV51947017; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ATP8B3 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 163/313 reads (52%) | catalogued as rs568761860; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 117/239 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs202247795, COSV104368601, COSV53499570; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNA11 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 127/274 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555702147, COSV50017316; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KIT | c.2466T>A p.N822K | Missense Mutation (SNP) | VAF 61/129 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MYL2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 158/381 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs104894368, CM961005, COSV57405974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 120/268 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs137854563, CM000777; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 165/396 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV61982533; called by muse, mutect2, varscan2
- RBM20 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 117/211 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397516607, COSV65706173, COSV65707634; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1327G>A p.G443R (on ENST00000373993 / NM_138932.2; = p.G435R on NM_014576.4) | Missense Mutation (SNP) | VAF 92/178 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.368); catalogued as rs1261105378; called by muse, mutect2, varscan2
- A1CF | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV50985594; called by muse, mutect2, varscan2
- A4GNT | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 154/300 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1052933001; called by muse, mutect2, varscan2
- ABCA13 | c.14320A>G p.T4774A | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV68946828; called by muse, mutect2, varscan2
- ABCA2 | c.6778C>T p.L2260F (on ENST00000614293; = p.L2230F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/168 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs1364115511; called by muse, mutect2
- ABCA3 | c.5011G>A p.E1671K | Missense Mutation (SNP) | VAF 209/465 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as COSV57060928; called by muse, mutect2, varscan2
- ABCA4 | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 164/392 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1216408517, COSV64675475; called by muse, mutect2, varscan2
- ABCA7 | c.5018C>T p.S1673F | Missense Mutation (SNP) | VAF 87/166 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV54029897; called by muse, mutect2, varscan2
- ABCC3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs578228776; called by muse, mutect2, varscan2
- ABCC3 | c.4146G>A p.M1382I | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as rs750587507, COSV53325337; called by muse, mutect2, varscan2
- ABCG2 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs561273590, COSV52945155; called by muse, mutect2, varscan2
- AC006059.2 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 110/253 reads (43%) | catalogued as rs186928386; called by muse, mutect2, varscan2
- ACAN | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as COSV100718122; called by muse, mutect2, varscan2
- ACBD3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 141/297 reads (47%) | catalogued as COSV64729752; called by muse, mutect2, varscan2
- ACCSL | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs199907490; called by muse, mutect2, varscan2
- ACSBG2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 128/282 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as rs751364914; called by muse, mutect2, varscan2
- ACSM2A | c.1189G>A p.D397N (on ENST00000219054; = p.D318N on NM_001308169.2) | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs750637232, COSV54582503; called by muse, mutect2, varscan2
- ACSM2B | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61656609; called by muse, mutect2, varscan2
- ADA | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 130/274 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs773557479, COSV65739994; called by muse, mutect2, varscan2
- ADAD1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs78087673, COSV99635305; called by muse, mutect2, varscan2
- ADAM2 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760693378; called by muse, mutect2, varscan2
- ADAM28 | c.306+8G>A | Splice Region (SNP) | VAF 52/93 reads (56%) | catalogued as rs775862538; called by muse, mutect2, varscan2
- ADAM28 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV56106893; called by muse, mutect2, varscan2
- ADAM29 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV63666064; called by muse, mutect2, varscan2
- ADAM32 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV65951006; called by muse, mutect2, varscan2
- ADAM7 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV51545300; called by muse, varscan2
- ADAMTS18 | c.2402C>T p.T801I | Missense Mutation (SNP) | VAF 242/243 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51403207; called by muse, mutect2, varscan2
- ADAMTS5 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs757271994, COSV53178718; called by muse, mutect2, varscan2
- ADAMTS6 | c.3031C>T p.R1011C | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs769190743, COSV58683484; called by muse, mutect2, varscan2
- ADAMTS9 | c.4318C>T p.P1440S | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV55778775; called by muse, varscan2
- ADAMTS9 | c.4291C>T p.R1431C | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as rs1170794686; called by muse, varscan2
- ADAMTS9 | c.2794G>A p.G932S | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs150178160; called by muse, mutect2, varscan2
- ADCY8 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 184/396 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as rs145360233, COSV53913924; called by muse, mutect2, varscan2
- ADGB | c.4852G>A p.D1618N | Missense Mutation (SNP) | VAF 99/193 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs544011156; called by muse, mutect2, varscan2
- ADGRB1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 202/412 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.734); catalogued as rs191669433; called by muse, mutect2, varscan2
- ADGRB3 | c.1572G>A p.W524* | Nonsense Mutation (SNP) | VAF 48/113 reads (42%) | catalogued as COSV65412416; called by muse, mutect2, varscan2
- ADGRE2 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 176/372 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.16); catalogued as COSV100216433; called by muse, mutect2, varscan2
- ADGRF5 | c.3308G>A p.W1103* | Nonsense Mutation (SNP) | VAF 104/284 reads (37%) | catalogued as COSV99346312; called by muse, mutect2, varscan2
- ADGRV1 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1045063485, COSV67989524; called by muse, mutect2, varscan2
- ADGRV1 | c.16732G>A p.D5578N | Missense Mutation (SNP) | VAF 89/90 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs747302299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFM | c.263A>T p.K88I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs181593933, COSV56920818; called by muse, mutect2, varscan2
- AGBL1 | c.489G>A p.R163= | Splice Region (SNP) | VAF 55/140 reads (39%) | catalogued as rs773202906, COSV69794090; called by muse, mutect2, varscan2
- AGXT2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 378/379 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV51491337; called by muse, mutect2, varscan2
- AK8 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 91/92 reads (99%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100049687; called by muse, mutect2, varscan2
- AKAP17A | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as COSV58309811; called by muse, mutect2, varscan2
- AKR1C1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV66499627; called by muse, mutect2, varscan2
- AKT2 | c.1266C>T p.L422= | Splice Region (SNP) | VAF 272/551 reads (49%) | catalogued as rs1568516568; called by muse, mutect2, varscan2
- ALB | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV55736203; called by muse, mutect2, varscan2
- ALDH1L1 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 113/244 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553676435; called by muse, mutect2, varscan2
- ALK | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 198/396 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.863); catalogued as rs766821017, COSV66556776; called by muse, mutect2, varscan2
- ALK | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 201/445 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs267599336; called by muse, mutect2, varscan2
- ALOX15 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as COSV53398043; called by muse, mutect2, varscan2
- ALPK3 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 106/183 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs774126835, COSV51935600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMBRA1 | c.1633C>T p.P545S (on ENST00000458649 / NM_001367468.1; = p.P455S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 169/171 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs771074894; called by muse, mutect2, varscan2
- ANHX | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 230/231 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs1351202474; called by muse, mutect2, varscan2
- ANK1 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 136/390 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1427563866; called by muse, mutect2, varscan2
- ANK3 | c.4084G>A p.G1362R (on ENST00000280772 / NM_001320874.2; = p.G496R on NM_001149.3) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777874; called by muse, mutect2, varscan2
- ANKRA2 | c.289+2T>C p.X97_splice | Splice Site (SNP) | VAF 26/26 reads (100%) | catalogued as rs1452226859; called by muse, mutect2
- ANKRD24 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs376089361; called by muse, mutect2, varscan2
- ANKRD30A | c.2500G>A p.G834R (on ENST00000611781; = p.G778R on NM_052997.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV64612412, COSV99071049; called by mutect2, varscan2
- ANKRD62 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV58412962; called by muse, mutect2, varscan2
- ANO4 | c.607G>A p.D203N (on ENST00000392977 / NM_001286615.2; = p.D168N on NM_178826.4) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs758365911, COSV54587105; called by muse, mutect2, varscan2
- ANPEP | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs759489673; called by muse, mutect2, varscan2
- ANXA13 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 109/203 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51623732; called by muse, mutect2, varscan2
- APC2 | c.4096C>T p.R1366C | Missense Mutation (SNP) | VAF 82/167 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1361316073; called by muse, mutect2, varscan2
- APOB | c.12460G>A p.E4154K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as rs767587977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 154/377 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61266759; called by muse, mutect2, varscan2
- ARGFX | c.860T>G p.M287R | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100544171; called by muse, mutect2, varscan2
- ARHGEF2 | c.2536C>T p.R846W (on ENST00000361247 / NM_001162383.2; = p.R818W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/156 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1426046254, COSV100560999; called by muse, mutect2, varscan2
- ARHGEF38 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.092); catalogued as rs1342007147; called by muse, varscan2
- ARID2 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 78/155 reads (50%) | catalogued as COSV57601825; called by muse, mutect2, varscan2
- ARID5B | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54416132; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, mutect2, varscan2
- ASCC2 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV57072882; called by muse, mutect2, varscan2
- ASIC1 | c.1206G>A p.G402= | Splice Region (SNP) | VAF 185/439 reads (42%) | catalogued as rs1201469889; called by muse, mutect2, varscan2
- ASXL2 | c.4124C>T p.P1375L | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1255700047; called by muse, mutect2, varscan2
- ATAD5 | c.1663C>A p.L555M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.293); catalogued as COSV58972631, COSV58978300; called by muse, mutect2, varscan2
- ATP10D | c.3335A>G p.N1112S | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as rs747735220; called by muse, mutect2, varscan2
- ATP13A1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 212/461 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759381799, COSV52290232; called by muse, mutect2, varscan2
- ATP13A2 | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 121/284 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs55635527; called by muse, mutect2, varscan2
- ATP1A3 | c.2399A>G p.N800S (on ENST00000545399 / NM_001256214.2; = p.N787S on NM_152296.5) | Missense Mutation (SNP) | VAF 189/392 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV57490034; called by muse, mutect2, varscan2
- ATP8B4 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748152515, COSV52717553; called by muse, mutect2, varscan2
- ATR | c.6620C>T p.S2207F | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV63390218; called by muse, mutect2, varscan2
- AXDND1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs868380930, COSV62648005; called by muse, mutect2, varscan2
- B4GALNT1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as rs1175256509; called by muse, mutect2, varscan2
- BAIAP3 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs760205376, COSV50103879, COSV99136177; called by muse, mutect2, varscan2
- BAP1 | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56235708; called by muse, mutect2, varscan2
- BCL2L10 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 180/434 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs758841562; called by muse, mutect2, varscan2
- BNC1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 184/394 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61758856; called by muse, mutect2, varscan2
- BRINP3 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 100/242 reads (41%) | catalogued as COSV66513576, COSV66524701; called by muse, varscan2
- C19orf47 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751821059; called by muse, mutect2, varscan2
- C1QTNF9B | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65943938; called by muse, mutect2, varscan2
- C1QTNF9B | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); catalogued as rs752036686; called by muse, mutect2, varscan2
- C1orf87 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV64598748; called by muse, mutect2
- C2orf78 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV68518166; called by muse, mutect2, varscan2
- C2orf80 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs267599173; called by muse, mutect2, varscan2
- C6orf15 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99456631; called by muse, varscan2
- C8A | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 293/642 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs760124872; called by muse, mutect2, varscan2
- C9 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs757060107, COSV54676570; called by muse, mutect2, varscan2
- CACNA1E | c.1056G>A p.G352= | Splice Region (SNP) | VAF 109/222 reads (49%) | catalogued as COSV62392543, COSV62418341; called by muse, varscan2
- CACNA1E | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 115/224 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62388732; called by muse, varscan2
- CACNA1H | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 218/416 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as rs1396673003, COSV61992090; called by muse, mutect2, varscan2
- CALB2 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100226083, COSV56939553; called by muse, mutect2, varscan2
- CARMIL2 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 85/85 reads (100%) | catalogued as COSV58026548, COSV58027649; called by muse, mutect2, varscan2
- CASP14 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99693101; called by muse, mutect2, varscan2
- CASR | c.2764G>A p.E922K (on ENST00000490131; = p.E999K on NM_000388.4) | Missense Mutation (SNP) | VAF 266/546 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99948333; called by muse, varscan2
- CATSPERB | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as rs1215491838, COSV56426370; called by muse, mutect2, varscan2
- CATSPERD | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as rs191427801; called by muse, mutect2, varscan2
- CATSPERG | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs140177794, COSV53048178; called by muse, mutect2, varscan2
- CBL | c.1096-2A>T p.X366_splice | Splice Site (SNP) | VAF 68/134 reads (51%) | catalogued as COSV50651087; called by muse, mutect2, varscan2
- CC2D2B | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV100729324; called by muse, mutect2, varscan2
- CCDC166 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1554616721, COSV72638820; called by muse, mutect2, varscan2
- CCDC54 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV53758288; called by muse, mutect2, varscan2
- CCDC87 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1480604332; called by muse, mutect2, varscan2
- CCDC88C | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs886916252, COSV66241642; called by muse, mutect2, varscan2
- CCDC92 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.12); catalogued as rs143142884; called by muse, mutect2, varscan2
- CCER1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs1412453346; called by muse, mutect2, varscan2
- CCKAR | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484342891, COSV55160821, COSV55164441; called by muse, mutect2, varscan2
- CCKAR | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 134/285 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs769825338; called by muse, mutect2, varscan2
- CCNQ | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 158/158 reads (100%) | catalogued as COSV52343985; called by muse, mutect2, varscan2
- CD163 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV63135893; called by muse, mutect2, varscan2
- CD2BP2 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs748668169; called by muse, mutect2, varscan2
- CD53 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as rs190729207, COSV54761318; called by muse, mutect2, varscan2
- CD6 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.437); catalogued as rs1234192046, COSV100533134, COSV57836291; called by muse, mutect2, varscan2
- CD84 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751746966, COSV60867000; called by muse, mutect2, varscan2
- CDC6 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 134/284 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs866378978, COSV52931322; called by muse, mutect2, varscan2
- CDK13 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 39/65 reads (60%) | catalogued as rs760503314, COSV99475854, COSV99475894; called by muse, mutect2, varscan2
- CDKAL1 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV51189877; called by muse, mutect2, varscan2
- CEP162 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV57625401; called by muse, mutect2, varscan2
- CEP162 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.025); catalogued as rs138904266; called by muse, mutect2, varscan2
- CEP290 | c.2832C>A p.F944L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV58355490; called by muse, mutect2, varscan2
- CEP76 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as rs1169303587; called by muse, mutect2, varscan2
- CEP89 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs772026609; called by muse, mutect2, varscan2
- CES5A | c.30G>T p.Q10H | Missense Mutation (SNP) | VAF 91/91 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs567508805; called by muse, mutect2, varscan2
- CFAP74 | c.4208C>T p.S1403L | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs769266515; called by muse, mutect2, varscan2
- CFB | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 323/678 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); catalogued as rs1411072076; called by muse, mutect2, varscan2
- CFTR | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs144720913, CM067769, COSV50060609, COSV50129630; called by muse, mutect2, varscan2
- CHADL | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs1045554218; called by muse, mutect2, varscan2
- CHD8 | c.5622C>A p.F1874L (on ENST00000646647 / NM_001170629.2; = p.F1595L on NM_020920.4) | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1301490795; called by muse, mutect2, varscan2
- CHI3L1 | c.257+2T>C p.X86_splice | Splice Site (SNP) | VAF 93/189 reads (49%) | catalogued as rs752438854; called by muse, mutect2, varscan2
- CHRNB1 | c.294C>G p.I98M | Missense Mutation (SNP) | VAF 73/437 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53439122; called by muse, mutect2, varscan2
- CLCN1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 129/335 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143506735, COSV58372528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLSTN3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs149690531; called by muse, mutect2, varscan2
- CNTN5 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as COSV54343066; called by muse, mutect2, varscan2
- CNTN6 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV63167352; called by muse, mutect2, varscan2
- CNTNAP2 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV62202038; called by muse, mutect2, varscan2
- CNTNAP2 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 164/348 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs777946931, COSV62162609; called by muse, mutect2, varscan2
- COL15A1 | c.2291G>A p.G764D | Missense Mutation (SNP) | VAF 73/74 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773801695; called by muse, mutect2, varscan2
- COL20A1 | c.3512G>A p.G1171E | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58912963; called by muse, mutect2, varscan2
- COL21A1 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55154545; called by muse, mutect2, varscan2
- COL3A1 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 154/325 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.057); catalogued as rs1460396340, COSV100482331; called by muse, mutect2, varscan2
- COL4A4 | c.3223G>A p.G1075S | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100305920; called by muse, mutect2, varscan2
- COL4A6 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 76/76 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57860857; called by muse, mutect2, varscan2
- COL6A3 | c.6788G>A p.R2263Q | Missense Mutation (SNP) | VAF 261/560 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs779508804, COSV55082724, COSV55109613; called by muse, mutect2, varscan2
- COL6A3 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV55110000; called by muse, mutect2, varscan2
- COL6A6 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 117/217 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.191); catalogued as rs766329094, COSV62019088; called by muse, mutect2, varscan2
- COL7A1 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as COSV60395932; called by muse, mutect2, varscan2
- COL8A2 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs752761856, COSV57443475; called by muse, mutect2, varscan2
- COL9A1 | c.1631G>A p.G544D | Missense Mutation (SNP) | VAF 203/448 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1431958752, COSV100294757, COSV57878088; called by muse, mutect2, varscan2
- COLQ | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 160/386 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67524190; called by muse, varscan2
- COPZ1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746806623; called by muse, mutect2, varscan2
- CORO7 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs1270698708, COSV52028057; called by muse, mutect2, varscan2
- COX8C | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 47/47 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as rs199879752; called by muse, mutect2, varscan2
- CPED1 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV59997018, COSV60010339; called by muse, mutect2, varscan2
- CPLX1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100408266; called by muse, mutect2
- CPO | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as rs771644753, COSV55939003; called by muse, mutect2, varscan2
- CPSF3 | c.1953G>A p.R651= | Splice Region (SNP) | VAF 68/141 reads (48%) | catalogued as rs139245590; called by muse, mutect2, varscan2
- CPT1B | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 122/269 reads (45%) | catalogued as rs374942225; called by muse, mutect2, varscan2
- CPZ | c.550C>T p.R184C (on ENST00000360986 / NM_001014447.3; = p.R173C on NM_003652.3) | Missense Mutation (SNP) | VAF 252/512 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs149059553; called by muse, mutect2, varscan2
- CRACR2A | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 116/250 reads (46%) | catalogued as COSV61543472; called by muse, mutect2, varscan2
- CREBBP | c.3323C>T p.S1108L | Missense Mutation (SNP) | VAF 220/465 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52114165, COSV52118821; called by muse, mutect2, varscan2
- CREM | c.718C>T p.P240S (on ENST00000429130; = p.P16S on NM_182717.2) | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1449034717; called by muse, mutect2, varscan2
- CRHR2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1301686299; called by muse, mutect2, varscan2
- CRHR2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146042188; called by muse, mutect2, varscan2
- CSF2RA | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 125/280 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV62625025; called by muse, mutect2, varscan2
- CSMD1 | c.6100G>A p.G2034R (on ENST00000520002; = p.G2033R on NM_033225.6) | Missense Mutation (SNP) | VAF 163/378 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59320972; called by muse, mutect2, varscan2
- CSMD1 | c.4531G>A p.G1511R (on ENST00000520002; = p.G1510R on NM_033225.6) | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59319601, COSV59337029; called by muse, mutect2, varscan2
- CSMD1 | c.3847C>T p.H1283Y (on ENST00000520002; = p.H1282Y on NM_033225.6) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as rs1482502744; called by muse, mutect2, varscan2
- CST9L | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 175/341 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65407873; called by muse, mutect2, varscan2
- CST9L | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 178/352 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV65408154; called by muse, mutect2, varscan2
- CTLA4 | c.523T>C p.F175L | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV55593336; called by muse, mutect2, varscan2
- CXXC1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 85/468 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.84); catalogued as rs757203610, COSV53275758; called by muse, mutect2, varscan2
- CYP1A2 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 84/140 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV59661369; called by muse, mutect2, varscan2
- CYP24A1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761493926, COSV53773927; called by muse, mutect2, varscan2
- CYP2A6 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 148/314 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1488959980, COSV56534449; called by muse, mutect2, varscan2
- CYP3A43 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV99733106; called by muse, mutect2, varscan2
- CYP4B1 | c.183C>T p.I61= | Splice Region (SNP) | VAF 79/176 reads (45%) | catalogued as COSV99597523; called by muse, mutect2, varscan2
- CYP4F2 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 112/248 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763027713, COSV55616039, COSV55618064; called by muse, varscan2
- CYP7B1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1477692961; called by muse, mutect2, varscan2
- DBF4B | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs757573915; called by muse, mutect2, varscan2
- DCAF4L1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 88/130 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV60787077; called by muse, mutect2, varscan2
- DDIAS | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV61271438; called by muse, mutect2, varscan2
- DDX47 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV61912128; called by muse, mutect2, varscan2
- DENND4A | c.5192C>T p.P1731L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as rs761508769, COSV71265346; called by muse, mutect2, varscan2
- DENND4A | c.5191C>T p.P1731S | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as rs764864062; called by muse, mutect2, varscan2
- DEPDC5 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 147/299 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs867743289, COSV56695845; called by muse, mutect2, varscan2
- DGAT2L6 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60717511; called by muse, mutect2
- DGAT2L6 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100284172; called by muse, mutect2
- DLGAP2 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 126/243 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV70100854; called by muse, mutect2, varscan2
- DNAH17 | c.9507G>A p.M3169I | Missense Mutation (SNP) | VAF 190/488 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV67757530; called by muse, mutect2
- DNAH3 | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as COSV54520229; called by muse, mutect2, varscan2
- DNAH7 | c.8087C>T p.S2696F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56768015; called by muse, mutect2, varscan2
- DNAH7 | c.4672G>A p.G1558R | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56780320; called by muse, mutect2, varscan2
- DNAH7 | c.3265C>T p.P1089S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs989543810; called by muse, mutect2, varscan2
- DNAJC5G | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 86/165 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV56080680, COSV56081314; called by muse, mutect2, varscan2
- DOCK4 | c.3602G>T p.R1201L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs181180606; called by muse, mutect2, varscan2
- DPPA4 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 193/432 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as rs748894803, COSV59512523; called by muse, mutect2, varscan2
- DSC3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 98/184 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112322768; called by muse, mutect2, varscan2
- DSG1 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 245/537 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57138627; called by muse, mutect2, varscan2
- DSG3 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 144/284 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs907432395; called by muse, mutect2, varscan2
- DYNC2H1 | c.3457C>T p.R1153W | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs544600765, COSV62091011; called by muse, mutect2, varscan2
- E4F1 | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 148/290 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs767312846, COSV57039187; called by muse, mutect2, varscan2
- EFEMP1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 161/300 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV62615606; called by muse, mutect2, varscan2
- EFHC2 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs760469358, COSV101375470, COSV69553493; called by muse, mutect2
- EGFLAM | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 221/222 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1391989293; called by muse, mutect2, varscan2
- EHMT2 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV64997725; called by muse, mutect2, varscan2
- ELF1 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 110/110 reads (100%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1218181125; called by muse, mutect2, varscan2
- ELL | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 139/272 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs759014608, COSV53211646; called by muse, mutect2, varscan2
- ELOA3 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 188/2940 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs748997785, COSV55293762; called by muse, mutect2
- ELP2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1208233624; called by muse, mutect2, varscan2
- ENAM | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as COSV68536004; called by muse, mutect2, varscan2
- EPHA1 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1389840241; called by muse, mutect2, varscan2
- EPHA2 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 149/271 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64452092, COSV64452513; called by muse, mutect2, varscan2
- EPHA5 | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.366); catalogued as COSV99897373; called by muse, mutect2, varscan2
- EPHA7 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs138876328; called by muse, mutect2, varscan2
- EPM2AIP1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 109/246 reads (44%) | catalogued as COSV51620433, COSV99212549; called by muse, mutect2, varscan2
- EPPK1 | c.6250C>T p.P2084S | Missense Mutation (SNP) | VAF 156/320 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as rs781812162; called by muse, mutect2
- EPPK1 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 130/252 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200175131; called by muse, mutect2, varscan2
- EREG | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as rs376236920, COSV55262382; called by muse, mutect2, varscan2
- ERICH3 | c.4088C>T p.S1363L | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751032690, COSV58619044; called by muse, mutect2, varscan2
- ETNK1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as rs1425418403; called by muse, mutect2, varscan2
- EYS | c.2403G>A p.W801* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as rs1424625518; called by muse, mutect2, varscan2
- EYS | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100677217, COSV60984721; called by mutect2, varscan2
- EZH1 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 70/156 reads (45%) | catalogued as rs1458266017, COSV52850540; called by muse, mutect2, varscan2
- F2RL3 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as rs372937570; called by muse, mutect2, varscan2
- FABP9 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV66911396; called by muse, mutect2, varscan2
- FAM107B | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs1339748592, COSV99474222; called by muse, mutect2, varscan2
- FAM135B | c.3577C>T p.R1193W | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180715939, COSV52715961, COSV99417794; called by muse, mutect2, varscan2
- FAM135B | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52718951, COSV52733976; called by muse, mutect2, varscan2
- FAM13C | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 165/292 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as COSV53242843, COSV99513589; called by muse, mutect2, varscan2
- FAM149A | c.1730C>T p.S577L (on ENST00000356371 / NM_001367768.2; = p.S286L on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 164/306 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs762001214; called by muse, mutect2, varscan2
- FAM3D | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 134/251 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1332134866, COSV100717046; called by muse, mutect2, varscan2
- FAM71D | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as rs769861811; called by muse, mutect2, varscan2
- FAM83B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.489); catalogued as COSV60925973; called by muse, mutect2, varscan2
- FAM83B | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 72/138 reads (52%) | catalogued as rs779268613; called by muse, mutect2, varscan2
- FAM83B | c.3011G>A p.G1004E | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs756470811, COSV60926764; called by muse, mutect2, varscan2
- FAP | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142146935, COSV51859814; called by muse, mutect2, varscan2
- FASN | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 214/443 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as rs762823912, COSV60752905; called by muse, mutect2, varscan2
- FASTKD2 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs1390288288; called by muse, mutect2, varscan2
- FAT2 | c.10978G>A p.D3660N | Missense Mutation (SNP) | VAF 108/108 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55814128; called by muse, mutect2, varscan2
- FAT3 | c.11401G>A p.E3801K | Missense Mutation (SNP) | VAF 174/354 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1435237876, COSV53118159, COSV53159525; called by muse, mutect2, varscan2
- FAT3 | c.12311G>A p.R4104Q | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1310916962, COSV53093990; called by muse, varscan2
- FAT4 | c.9487G>A p.E3163K | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs370088878, CM1311052; called by muse, mutect2, varscan2
- FBH1 | c.923C>T p.P308L (on ENST00000362091 / NM_178150.3; = p.P359L on NM_032807.4) | Missense Mutation (SNP) | VAF 80/156 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100758963; called by muse, varscan2
- FBXO24 | c.211G>A p.E71K (on ENST00000241071 / NM_033506.3; = p.E109K on NM_012172.5) | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs776297299, COSV53825559; called by muse, mutect2, varscan2
- FCGBP | c.9013C>T p.P3005S | Missense Mutation (SNP) | VAF 470/2626 reads (18%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.66); catalogued as rs748342735; called by muse, mutect2, varscan2
- FCGBP | c.5410C>T p.P1804S | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.86); catalogued as rs1284900274, COSV55449068; called by muse, mutect2
- FCRLA | c.448G>T p.E150* (on ENST00000367959; = p.E127* on NM_032738.4) | Nonsense Mutation (SNP) | VAF 137/253 reads (54%) | catalogued as rs781524210; called by muse, mutect2, varscan2
- FILIP1L | c.2586G>A p.W862* (on ENST00000354552 / NM_182909.3; = p.W622* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/136 reads (43%) | catalogued as COSV58776208; called by muse, mutect2, varscan2
- FLG | c.4687G>A p.E1563K | Missense Mutation (SNP) | VAF 242/484 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV100911527, COSV64242286; called by muse, varscan2
- FLG | c.4577G>A p.G1526E | Missense Mutation (SNP) | VAF 213/465 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as rs776816341, COSV64235652; called by muse, varscan2
- FLNB | c.6976C>T p.P2326S | Missense Mutation (SNP) | VAF 172/353 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211837552; called by muse, mutect2, varscan2
- FLNC | c.5374G>A p.A1792T | Missense Mutation (SNP) | VAF 167/374 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201348102; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FLRT3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539605227; called by muse, mutect2, varscan2
- FMN2 | c.4402C>T p.R1468C | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs748812254, COSV100144530, COSV60425638; called by muse, mutect2, varscan2
- FOXK1 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 137/262 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); catalogued as rs1373940205; called by muse, mutect2, varscan2
- FREM1 | c.1713G>A p.M571I | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV66521139; called by muse, mutect2
- FREM3 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV61682661; called by muse, mutect2, varscan2
- FRMPD4 | c.1916T>A p.L639Q | Missense Mutation (SNP) | VAF 88/88 reads (100%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.099); catalogued as COSV66211893; called by muse, mutect2, varscan2
- FRY | c.6706C>T p.P2236S | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.145); catalogued as COSV66573682; called by muse, mutect2, varscan2
- FRY | c.6997G>A p.D2333N | Missense Mutation (SNP) | VAF 76/76 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs755355616; called by muse, mutect2, varscan2
- FSCN3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 147/308 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs768392595; called by muse, mutect2, varscan2
- FYB2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs868085118; called by muse, mutect2
- G6PC | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 114/246 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1555560217, COSV53832405; called by muse, mutect2, varscan2
- GABPB2 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 86/189 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as COSV64460494; called by muse, mutect2, varscan2
- GABRE | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs867877489, COSV100944370; called by muse, mutect2, varscan2
- GAK | c.3734G>A p.G1245E | Missense Mutation (SNP) | VAF 173/318 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs762130890, COSV58503374; called by muse, mutect2, varscan2
- GAK | c.3733G>A p.G1245R | Missense Mutation (SNP) | VAF 169/313 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779444679; called by muse, mutect2, varscan2
- GAL3ST4 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs1479748186; called by muse, mutect2
- GALNT13 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 95/225 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101222185; called by muse, mutect2, varscan2
- GALNT17 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61148861; called by muse, mutect2, varscan2
- GALNT9 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.537); catalogued as rs1303789264; called by muse, mutect2, varscan2
- GAPVD1 | c.3971G>A p.R1324Q (on ENST00000394104; = p.R1333Q on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs376056156; called by muse, mutect2, varscan2
- GATA3 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 245/528 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV60522371; called by muse, mutect2, varscan2
- GBA | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs765693058; called by muse, mutect2, varscan2
- GBA3 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs373204012; called by muse, mutect2, varscan2
- GCKR | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 175/426 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs761397252, COSV53106414; called by muse, mutect2, varscan2
- GCNT7 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 123/261 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs550349236, COSV50129486; called by muse, mutect2, varscan2
- GCOM1 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147311786; called by muse, mutect2, varscan2
- GJA1 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 202/470 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.646); catalogued as rs1265740574, COSV56997529; called by muse, mutect2, varscan2
- GJB2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV101241508; called by muse, mutect2, varscan2
- GMNC | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as rs897912665; called by muse, mutect2, varscan2
- GNL3L | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.402); catalogued as rs1483034249; called by muse, mutect2, varscan2
- GOLGA8Q | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs997704265; called by mutect2, varscan2
- GOLGA8Q | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 46/311 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1378199697; called by mutect2, varscan2
- GPR22 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.86); PolyPhen benign (0.026); catalogued as COSV51765150; called by muse, mutect2, varscan2
- GPR83 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV54718707, COSV54720284; called by muse, mutect2, varscan2
- GPRC6A | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775109241, COSV59951289; called by muse, mutect2, varscan2
- GRIA3 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 53/54 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52049378; called by muse, mutect2, varscan2
- GRIK2 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs1180999815, COSV59718133; called by muse, mutect2, varscan2
- GRIK2 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 120/255 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59758807; called by muse, mutect2, varscan2
- GRIK3 | c.2655G>A p.M885I | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100902135; called by muse, mutect2, varscan2
- GRM3 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs772318511; called by muse, mutect2, varscan2
- GSS | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 170/385 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.052); catalogued as rs763001933; called by muse, mutect2, varscan2
- GTF2IRD1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 98/281 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as rs139144176, COSV56086308; called by muse, mutect2, varscan2
- GZMM | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs1165398617, COSV52743364; called by muse, varscan2
- H1-6 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 168/382 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201733307; called by muse, mutect2, varscan2
- HDAC9 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs867599481, COSV67785345; called by muse, mutect2, varscan2
- HDAC9 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 100/189 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV67773418; called by muse, mutect2, varscan2
- HECW2 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs376126888; called by muse, mutect2, varscan2
- HERC2 | c.6115G>A p.V2039I | Missense Mutation (SNP) | VAF 253/730 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1378157705; called by muse, mutect2, varscan2
- HERC4 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.211); catalogued as COSV53269178; called by muse, mutect2, varscan2
- HERPUD2 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV60947843; called by muse, mutect2, varscan2
- HLA-DPA1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.542); catalogued as rs764514281, COSV70088498; called by muse, mutect2, varscan2
- HLA-DQB2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 104/278 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs746713265; called by muse, varscan2
- HMCN1 | c.8887C>T p.P2963S | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV54911523; called by muse, mutect2, varscan2
- HMCN1 | c.11536G>T p.V3846L | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.978); catalogued as rs1015938577; called by muse, mutect2, varscan2
- HNRNPU | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 263/594 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs570495195; called by muse, mutect2, varscan2
- HPCAL1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 101/231 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1558537435, COSV100324165; called by muse, mutect2, varscan2
- HPR | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs367988509, COSV57184029; called by muse, mutect2, varscan2
- HSPG2 | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 116/276 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs1450403526; called by muse, mutect2, varscan2
- HYDIN | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1244006572; called by muse, mutect2, varscan2
- IGHG3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 153/154 reads (99%) | SIFT tolerated (0.3); PolyPhen benign (0.192); catalogued as rs768763240; called by muse, mutect2, varscan2
- IGHV4-4 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 285/288 reads (99%) | catalogued as rs549396458; called by muse, mutect2, varscan2
- IGHV4-59 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 300/371 reads (81%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.163); catalogued as rs782792143; called by muse, mutect2, varscan2
- IGKV1-39 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs780534208; called by mutect2, varscan2
- IGLV5-52 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs1363909807; called by muse, mutect2, varscan2
- IL1F10 | c.119-5C>T | Splice Region (SNP) | VAF 152/365 reads (42%) | catalogued as rs1256987546; called by muse, mutect2
- IL1RL1 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52118409, COSV52120584; called by muse, mutect2, varscan2
- IL21R | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV61973349; called by muse, mutect2, varscan2
- IQCE | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 174/364 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100383791; called by muse, mutect2, varscan2
- IRGC | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 140/280 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs759272396; called by muse, mutect2, varscan2
- ITGAV | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs559278598, COSV53709744; called by muse, mutect2, varscan2
- ITGAX | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 147/283 reads (52%) | catalogued as COSV51649266; called by muse, mutect2, varscan2
- ITPR1 | c.8069G>A p.G2690E (on ENST00000354582; = p.G2635E on NM_002222.7) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100233644; called by muse, mutect2, varscan2
- JADE2 | c.1610C>G p.S537W | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50921464; called by muse, mutect2, varscan2
- JAK3 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 100/203 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV71687973; called by muse, mutect2, varscan2
- JAKMIP1 | c.2455C>T p.L819F | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68956456; called by muse, mutect2, varscan2
- JMJD7 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 102/233 reads (44%) | catalogued as COSV59824184; called by muse, mutect2, varscan2
- JRK | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs781863311, COSV101401061; called by muse, mutect2, varscan2
- KCNB2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 103/181 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050367; called by muse, mutect2, varscan2
- KCNC3 | c.2156G>A p.G719D | Missense Mutation (SNP) | VAF 148/280 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV65387059; called by muse, mutect2, varscan2
- KCNH7 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100147340; called by muse, mutect2, varscan2
- KCNQ5 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59653227; called by muse, mutect2, varscan2
- KCTD16 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 207/207 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.187); catalogued as COSV72577412; called by muse, mutect2, varscan2
- KDM4B | c.1516C>T p.L506F | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1447970270, COSV99347622; called by muse, mutect2, varscan2
- KDM5C | c.1168del p.R390Gfs*40 | Frame Shift Del (DEL) | VAF 177/243 reads (73%) | catalogued as COSV64769600; called by mutect2, pindel, varscan2
- KIAA1217 | c.5189C>T p.S1730L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as rs1189512254, COSV56812591; called by muse, mutect2, varscan2
- KIF13B | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769121640, COSV73054662; called by muse, mutect2, varscan2
- KIF14 | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100950534; called by muse, mutect2, varscan2
- KIF17 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 129/318 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV99928242; called by muse, mutect2, varscan2
- KIF21B | c.3376G>A p.G1126S | Missense Mutation (SNP) | VAF 136/308 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as rs1382480222; called by muse, mutect2, varscan2
- KIF26B | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV63654264; called by muse, mutect2, varscan2
- KIRREL1 | c.2033C>A p.T678K | Missense Mutation (SNP) | VAF 97/176 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs201145714; called by muse, mutect2, varscan2
- KMT2B | c.5893C>T p.P1965S | Missense Mutation (SNP) | VAF 106/182 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763584372; called by muse, mutect2, varscan2
- KMT2D | c.12413C>T p.S4138F | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1281537769, COSV56423898; called by muse, mutect2, varscan2
- KMT2D | c.7085C>T p.P2362L | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1220931991; called by muse, mutect2, varscan2
- KMT2E | c.3094C>T p.P1032S | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs754816791; called by muse, mutect2, varscan2
- KNSTRN | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51103388, COSV51103522; called by muse, mutect2, varscan2
- KRT222 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67499022; called by muse, mutect2, varscan2
- KRT4 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 176/355 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs770618586; called by muse, mutect2, varscan2
- KRT6A | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 115/412 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs1339399303; called by muse, mutect2, varscan2
- KRT79 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 289/556 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as COSV57942038; called by muse, mutect2, varscan2
- KRTAP9-9 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 254/549 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV101223552; called by muse, mutect2, varscan2
- KYAT3 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777248500, COSV53102002; called by muse, mutect2, varscan2
- L3MBTL1 | c.1201G>A p.E401K (on ENST00000418998 / NM_001377303.1; = p.E311K on NM_015478.7) | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.824); catalogued as COSV64228887; called by muse, mutect2, varscan2
- LCORL | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1281283272; called by muse, mutect2, varscan2
- LCT | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 164/342 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV51551548; called by muse, mutect2, varscan2
- LILRA4 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 137/291 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759751078, COSV52492084, COSV99393015; called by muse, mutect2, varscan2
- LIN28A | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 187/356 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV54262077; called by muse, mutect2, varscan2
- LIN9 | c.862C>T p.P288S (on ENST00000366808 / NM_001270410.2; = p.P233S on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs267598393, COSV60247060; called by muse, mutect2, varscan2
- LIPE | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54921680; called by muse, mutect2, varscan2
- LIPF | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.464); catalogued as rs1344968098; called by muse, mutect2, varscan2
- LMLN | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs778670724, COSV57604251; called by muse, mutect2, varscan2
- LPO | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 93/192 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764112101, COSV99229441; called by muse, mutect2, varscan2
- LRG1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 185/399 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs765306791, COSV56705348; called by muse, mutect2, varscan2
- LRIT2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.564); catalogued as rs748493791; called by muse, mutect2, varscan2
- LRP1 | c.8128C>T p.P2710S | Missense Mutation (SNP) | VAF 67/115 reads (58%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as COSV54511609; called by muse, mutect2, varscan2
- LRP1B | c.10282G>A p.E3428K | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67275491; called by muse, mutect2, varscan2
- LRP1B | c.7523C>T p.S2508F | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1393251553, COSV67193597; called by muse, mutect2, varscan2
- LRP2 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 162/350 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs766975916; called by muse, mutect2, varscan2
- LRRC3C | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100932483; called by muse, mutect2, varscan2
- LRRIQ1 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV67837634; called by muse, mutect2, varscan2
- LRRTM4 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 90/212 reads (42%) | catalogued as COSV69138907; called by muse, mutect2, varscan2
- LY75 | c.4484G>A p.G1495E | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV55101952; called by muse, mutect2, varscan2
- LY96 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs199845476; called by muse, mutect2, varscan2
- MACC1 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV60546206; called by muse, mutect2, varscan2
- MADCAM1 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0.145); catalogued as COSV53127478; called by muse, varscan2
- MAP2 | c.2017C>T p.L673F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); catalogued as rs370470543; called by muse, mutect2, varscan2
- MAP2K2 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 179/367 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs759998177, COSV99502601; called by muse, mutect2, varscan2
- MAP3K19 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs146312185; called by muse, mutect2, varscan2
- MAP3K6 | c.1140C>T p.H380= | Splice Region (SNP) | VAF 58/121 reads (48%) | catalogued as COSV62888903; called by muse, mutect2, varscan2
- MAP6 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1038563574, COSV59077721; called by muse, mutect2, varscan2
- MARCHF7 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52029520; called by muse, mutect2, varscan2
- MARS1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 106/250 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as COSV56254909; called by muse, mutect2, varscan2
- MDN1 | c.8225C>T p.A2742V | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as rs774826637, COSV65517651; called by muse, mutect2, varscan2
- MDN1 | c.7309G>A p.D2437N | Missense Mutation (SNP) | VAF 197/440 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as COSV65527282; called by muse, mutect2, varscan2
- METRNL | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.226); catalogued as COSV60762148; called by muse, mutect2, varscan2
- MGAM | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.107); catalogued as rs1475463265, COSV71885216; called by muse, mutect2, varscan2
- MGAM | c.3655G>A p.G1219R | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99071111; called by muse, mutect2, varscan2
- MGAM | c.4289G>A p.G1430E | Missense Mutation (SNP) | VAF 160/339 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs1348650177, COSV72075846; called by muse, mutect2, varscan2
- MGAM2 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.093); catalogued as rs1469143931; called by muse, mutect2, varscan2
- MGLL | c.842C>T p.S281F (on ENST00000398104 / NM_001003794.2; = p.S291F on NM_007283.6) | Missense Mutation (SNP) | VAF 120/294 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54023933; called by muse, mutect2, varscan2
- MICB | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as COSV52857346; called by muse, mutect2, varscan2
- MKI67 | c.7754C>T p.P2585L | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.287); catalogued as rs138254987, COSV64077666; called by muse, mutect2, varscan2
- MLIP | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769959762, COSV51426013; called by muse, mutect2, varscan2
- MMP21 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1176673600; called by muse, mutect2, varscan2
- MMP9 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476025308; called by muse, mutect2, varscan2
- MMRN1 | c.929A>T p.Q310L | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as rs755892330; called by muse, mutect2, varscan2
- MOGAT2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 176/307 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99549412; called by muse, mutect2, varscan2
- MPPE1 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 137/276 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1249049646; called by muse, mutect2, varscan2
- MPRIP | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 106/223 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs754649333; called by muse, varscan2
- MRC2 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs765509790, COSV57640857; called by muse, mutect2, varscan2
- MSH4 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as COSV54197607; called by muse, mutect2, varscan2
- MSRB1 | c.204+8G>A | Splice Region (SNP) | VAF 177/398 reads (44%) | catalogued as rs889152936; called by muse, mutect2, varscan2
- MST1L | n.337G>A | Splice Region (SNP) | VAF 93/335 reads (28%) | catalogued as rs750198440; called by mutect2, varscan2
- MTMR3 | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 128/266 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1295984806, COSV100071480; called by muse, mutect2, varscan2
- MTMR7 | c.1328G>A p.S443N | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1484097457; called by muse, mutect2, varscan2
- MTPAP | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 117/273 reads (43%) | catalogued as rs773094167, COSV53934807; called by muse, mutect2, varscan2
- MUC16 | c.39589A>T p.S13197C | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV101109929; called by muse, mutect2, varscan2
- MUC16 | c.31817C>T p.T10606I | Missense Mutation (SNP) | VAF 87/147 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV101199451; called by muse, mutect2, varscan2
- MUC16 | c.23108C>T p.S7703F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV67451909; called by muse, mutect2, varscan2
- MUC16 | c.20876C>T p.S6959F | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV67454402; called by muse, mutect2, varscan2
- MUC16 | c.18704C>T p.P6235L | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV67481556; called by muse, mutect2, varscan2
- MUC16 | c.16856G>A p.W5619* | Nonsense Mutation (SNP) | VAF 112/260 reads (43%) | catalogued as rs768465817; called by muse, mutect2, varscan2
- MUC3A | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious, low confidence (0); catalogued as rs754858120, COSV60225984; called by muse, mutect2, varscan2
- MUC4 | c.6020C>T p.S2007F | Missense Mutation (SNP) | VAF 148/740 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1459168065, COSV62204726; called by muse, mutect2
- MXRA5 | c.6016G>A p.E2006K | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV54230410; called by muse, mutect2, varscan2
- MXRA5 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866233220, COSV54222468; called by muse, mutect2, varscan2
- MXRA5 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 103/104 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99475959; called by muse, mutect2, varscan2
- MXRA8 | c.377-4G>A | Splice Region (SNP) | VAF 246/518 reads (47%) | catalogued as rs747801925; called by muse, mutect2, varscan2
- MYH1 | c.5216C>T p.S1739F | Missense Mutation (SNP) | VAF 129/267 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV56844579; called by muse, mutect2, varscan2
- MYH15 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV56319856, COSV99843346; called by muse, mutect2, varscan2
- MYH2 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 221/518 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV55441089; called by muse, mutect2
- MYH9 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 200/411 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53393635; called by muse, mutect2, varscan2
- MYO1F | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57792606; called by muse, mutect2, varscan2
- MYO7A | c.4729G>A p.G1577R | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV68684711; called by muse, varscan2
- MYO7A | c.6052-1G>A p.X2018_splice | Splice Site (SNP) | VAF 39/80 reads (49%) | catalogued as rs752638379, COSV68684677; called by muse, mutect2, varscan2
- MYT1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as rs377464140; called by muse, varscan2
- NCR2 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV66101487; called by muse, mutect2, varscan2
- NDST4 | c.560A>T p.N187I | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52113970; called by muse, mutect2, varscan2
- NEB | c.18761G>A p.G6254E | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99426520; called by muse, mutect2, varscan2
- NEB | c.13144G>A p.E4382K | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs1479911719; called by muse, mutect2, varscan2
- NF1 | c.6687G>A p.W2229* (on ENST00000358273 / NM_001042492.3; = p.W2208* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 110/231 reads (48%) | catalogued as CM950850, COSV62212095; called by muse, mutect2, varscan2
- NF2 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 170/399 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as CD962106, COSV58530888; called by muse, mutect2, varscan2
- NFIA | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 90/177 reads (51%) | catalogued as rs867909615; called by muse, mutect2, varscan2
- NINL | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV54003379; called by muse, mutect2, varscan2
- NKAIN4 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 128/310 reads (41%) | catalogued as COSV100941639; called by muse, mutect2, varscan2
- NLGN4Y | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 267/272 reads (98%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs907067999; called by muse, mutect2, varscan2
- NLRP12 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 197/364 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1362127424, COSV60755339; called by muse, mutect2, varscan2
- NLRP2 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 103/193 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as rs776814479, COSV54759606; called by muse, mutect2, varscan2
- NLRP3 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1374519501; called by muse, mutect2, varscan2
- NLRP3 | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 153/315 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60230102; called by muse, mutect2, varscan2
- NLRP4 | c.1492T>A p.F498I | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs867737171; called by muse, mutect2, varscan2
- NLRP5 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 81/150 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as rs199737074; called by muse, mutect2, varscan2
- NNMT | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs769948100; called by muse, mutect2, varscan2
- NOBOX | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 135/285 reads (47%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.041); catalogued as COSV56192875; called by muse, mutect2, varscan2
- NOL12 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs371438425; called by muse, mutect2, varscan2
- NOS2 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs754161294; called by muse, mutect2, varscan2
- NOS3 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs1490923378, COSV52491557; called by muse, mutect2, varscan2
- NOSTRIN | c.856G>A p.E286K (on ENST00000317647 / NM_001039724.4; = p.E208K on NM_052946.3) | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV58320708; called by muse, mutect2, varscan2
- NPAP1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs143409729; called by muse, varscan2
- NPAS4 | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs267603127; called by muse, mutect2, varscan2
- NPIPB2 | c.845C>T p.P282L (on ENST00000399147; = p.P142L on NM_001355514.1) | Missense Mutation (SNP) | VAF 160/763 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs1222109967; called by muse, mutect2, varscan2
- NPIPB4 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 85/477 reads (18%) | SIFT tolerated, low confidence (0.99); PolyPhen possibly damaging (0.649); catalogued as rs1312439263; called by muse, varscan2
- NRAP | c.4604C>T p.P1535L (on ENST00000359988 / NM_001322945.2; = p.P1500L on NM_006175.4) | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921144685, COSV63490847; called by muse, varscan2
- NRG1 | c.1255C>T p.P419S (on ENST00000405005 / NM_013964.5; = p.P424S on NM_013956.5) | Missense Mutation (SNP) | VAF 100/191 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772524774; called by muse, mutect2, varscan2
- NRG1 | c.1256C>T p.P419L (on ENST00000405005 / NM_013964.5; = p.P424L on NM_013956.5) | Missense Mutation (SNP) | VAF 98/187 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181470222, COSV55177846; called by muse, mutect2, varscan2
- NRK | c.3158A>G p.E1053G | Missense Mutation (SNP) | VAF 207/207 reads (100%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs754400354; called by muse, mutect2, varscan2
- NRSN1 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV101027310; called by muse, mutect2, varscan2
- NUGGC | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 95/192 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs955005459; called by muse, mutect2, varscan2
- NUGGC | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV58434848; called by muse, mutect2, varscan2
- NWD2 | c.4843C>T p.L1615F | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1380154390; called by muse, mutect2, varscan2
- OBP2B | c.75C>T p.I25= | Splice Region (SNP) | VAF 56/62 reads (90%) | catalogued as COSV100922814; called by muse, mutect2, varscan2
- OGDHL | c.2767C>T p.P923S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867750245, COSV65101316; called by muse, mutect2, varscan2
- OGDHL | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65100582; called by muse, mutect2, varscan2
- OR10J3 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 116/233 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs868734843, COSV59953696, COSV59955976; called by muse, mutect2, varscan2
- OR1A2 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs770955675; called by muse, mutect2, varscan2
- OR1A2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101126390; called by muse, mutect2, varscan2
- OR1F1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746066317, COSV100484439, COSV58961151; called by muse, mutect2, varscan2
- OR1Q1 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 98/99 reads (99%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99939206; called by muse, mutect2, varscan2
- OR1S2 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 124/296 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100224072; called by muse, varscan2
- OR2J2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.251); catalogued as rs1204408586; called by muse, mutect2, varscan2
- OR2M3 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 115/210 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV71758951; called by muse, mutect2, varscan2
- OR2T34 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 116/362 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV60899740; called by muse, mutect2, varscan2
- OR4A15 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as COSV59037495; called by muse, mutect2, varscan2
- OR4C15 | c.817G>A p.V273I (on ENST00000314644; = p.V219I on NM_001001920.2) | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.098); catalogued as rs1367446619; called by muse, mutect2, varscan2
- OR4C16 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1256354622, COSV58940623, COSV58940762; called by muse, mutect2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 116/285 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR5AP2 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs1486617293, COSV57259066; called by muse, mutect2, varscan2
- OR5B2 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 134/241 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.078); catalogued as COSV100222876; called by muse, mutect2, varscan2
- OR5D16 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as rs867879197, COSV65721582; called by muse, mutect2
- OR5I1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs766069607, COSV100041782, COSV56885194; called by muse, mutect2, varscan2
- OR5K2 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 110/208 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101415946; called by muse, mutect2, varscan2
- OR5M8 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 115/222 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV59116899; called by muse, mutect2, varscan2
- OR5T1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT tolerated (0.73); PolyPhen benign (0.049); catalogued as COSV57304969; called by muse, mutect2, varscan2
- OR9G4 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs138033916; called by muse, mutect2, varscan2
- OSMR | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV57091926; called by muse, mutect2, varscan2
- OSMR | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 289/289 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.644); catalogued as rs769344392, COSV57085792; called by muse, mutect2, varscan2
- OTOGL | c.3388C>T p.P1130S (on ENST00000547103; = p.P1121S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV101509062; called by muse, mutect2, varscan2
- OTOL1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs866445322, COSV60006028, COSV60006472; called by muse, mutect2, varscan2
- OXCT2 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312803048; called by muse, varscan2
- P2RY2 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs755322202; called by muse, mutect2
- PALD1 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.763); catalogued as rs533752583; called by muse, varscan2
- PALM3 | c.1603G>T p.E535* (on ENST00000340790; = p.E550* on NM_001145028.2) | Nonsense Mutation (SNP) | VAF 96/228 reads (42%) | catalogued as COSV54603103; called by muse, mutect2, varscan2
- PAPPA2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 179/399 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as COSV62780972; called by muse, mutect2, varscan2
- PAPPA2 | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 97/192 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs761015830; called by muse, mutect2, varscan2
- PAQR6 | c.609G>A p.R203= (on ENST00000292291 / NM_001272108.2; = p.R97= on NM_024897.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 80/190 reads (42%) | catalogued as COSV52744582; called by muse, mutect2, varscan2
- PARP15 | c.1276G>A p.D426N (on ENST00000464300 / NM_001113523.3; = p.D192N on NM_152615.2) | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs749555610, COSV59972128; called by muse, mutect2, varscan2
- PARP8 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 107/107 reads (100%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.163); catalogued as rs202205038, COSV55862044; called by muse, mutect2, varscan2
- PAX1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1229986699; called by muse, mutect2, varscan2
- PBRM1 | c.3154C>T p.R1052* (on ENST00000296302 / NM_001366071.2; = p.R1027* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 43/43 reads (100%) | catalogued as COSV56260610; called by muse, mutect2
- PCDH15 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV57301613; called by muse, mutect2, varscan2
- PCDH18 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs868086398; called by muse, mutect2, varscan2
- PCDHA12 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 169/169 reads (100%) | catalogued as rs1554167756; called by muse, mutect2, varscan2
- PCDHB10 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 200/201 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53384662; called by muse, mutect2, varscan2
- PCDHGB3 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 89/89 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV53950994; called by muse, mutect2, varscan2
- PCK1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1185656022; called by muse, mutect2, varscan2
- PCSK4 | c.731C>G p.S244W | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766570695; called by muse, mutect2, varscan2
- PDCD10 | c.99A>G p.L33= | Splice Region (SNP) | VAF 78/188 reads (41%) | catalogued as rs369606517, COSV101208570; called by muse, mutect2, varscan2
- PDE4A | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 121/232 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs758300846; called by muse, mutect2, varscan2
- PDE4B | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs1396000316, COSV100305699; called by muse, mutect2, varscan2
- PDZD3 | c.526G>A p.V176M (on ENST00000531114; = p.V110M on NM_024791.4) | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs746197425; called by muse, mutect2, varscan2
- PDZD7 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.935); catalogued as COSV100932142; called by muse, mutect2, varscan2
- PDZRN4 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV68402795; called by muse, mutect2, varscan2
- PEG3 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV55634402; called by muse, mutect2, varscan2
- PGM2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs201199256; called by muse, mutect2, varscan2
- PGM5 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 88/88 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); catalogued as rs782232692, COSV67167563; called by muse, mutect2, varscan2
- PHOX2B | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 194/296 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV56932016; called by muse, varscan2
- PHOX2B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 223/328 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV56931113; called by muse, varscan2
- PICK1 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs895122027; called by muse, mutect2, varscan2
- PIK3C2G | c.3475G>A p.E1159K (on ENST00000676171; = p.E1118K on NM_004570.5) | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); catalogued as COSV56815909; called by muse, mutect2, varscan2
- PIK3IP1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53223442, COSV53223515; called by muse, mutect2, varscan2
- PIWIL2 | c.1715G>A p.R572K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs779755341, COSV63250459; called by muse, mutect2, varscan2
- PKHD1L1 | c.10151G>A p.G3384E | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV65744958; called by muse, mutect2, varscan2
- PLA2G4A | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66557856; called by muse, mutect2, varscan2
- PLCE1 | c.3604G>A p.G1202R | Missense Mutation (SNP) | VAF 281/578 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752714644; called by muse, mutect2, varscan2
- PLCZ1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs1308051972, COSV56855967; called by muse, mutect2, varscan2
- POFUT1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 245/491 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as rs745383992, COSV65337185; called by muse, mutect2, varscan2
- POLD1 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1161281976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3B | c.3308C>T p.S1103F | Missense Mutation (SNP) | VAF 188/380 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV57278583; called by muse, mutect2, varscan2
- POPDC2 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 120/226 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs201668102; called by muse, mutect2, varscan2
- POTEH | c.1456C>G p.P486A | Missense Mutation (SNP) | VAF 128/578 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs1463585163; called by muse, varscan2
- POTEJ | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1240795297; called by mutect2, varscan2
- PPBP | c.363G>C p.L121F | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779348146; called by muse, mutect2, varscan2
- PPDPFL | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1212695465, COSV57462436; called by muse, mutect2, varscan2
- PPM1E | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100376484; called by muse, mutect2, varscan2
- PPP1R3A | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 113/226 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52882141; called by muse, mutect2, varscan2
- PRAME | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.52); catalogued as rs1023315891, COSV67162352; called by muse, mutect2
- PRB3 | c.914G>A p.G305E (on ENST00000381842; = p.G347E on NM_006249.5) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as rs760108848, COSV99686085; called by muse, mutect2, varscan2
- PREX2 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs529924687, COSV55750983, COSV55758850; called by muse, mutect2, varscan2
- PRKACG | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 175/175 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760478735, COSV99599602; called by muse, mutect2, varscan2
- PRKAR2B | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1213025838; called by muse, mutect2, varscan2
- PRMT7 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 109/109 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs529555935; called by muse, mutect2, varscan2
- PRODH2 | c.405C>T p.L135= (on ENST00000301175; = p.L59= on NM_021232.2 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 64/108 reads (59%) | catalogued as rs371889697; called by muse, mutect2, varscan2
- PRR23C | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as rs1248768056; called by muse, mutect2, varscan2
- PRR33 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 46/46 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs796839221; called by muse, mutect2, varscan2
- PRSS35 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63801154; called by muse, mutect2, varscan2
- PSD | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs779421908; called by muse, mutect2, varscan2
- PTPN9 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 108/223 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs779716989; called by muse, mutect2, varscan2
- PTPRK | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 104/210 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781634717; called by muse, mutect2, varscan2
- PTPRN2 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 297/553 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV67030896; called by muse, mutect2, varscan2
- PTPRQ | c.4476G>A p.W1492* (on ENST00000616559; = p.W1450* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV57043844; called by muse, mutect2, varscan2
- PTPRR | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355830722, COSV51728664; called by muse, mutect2, varscan2
- PTPRT | c.2506G>A p.G836R | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs745346735, COSV100626660, COSV61982047; called by muse, mutect2, varscan2
- PTPRT | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 131/230 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61973542; called by muse, mutect2, varscan2
- PWWP3B | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs781758273; called by muse, varscan2
- PXDNL | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 137/292 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV62496833; called by muse, mutect2, varscan2
- PXDNL | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 216/500 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.029); catalogued as COSV100685732; called by muse, mutect2
- PYGB | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs199655911; called by muse, mutect2, varscan2
- PZP | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54365693; called by muse, mutect2, varscan2
- RAG1 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 144/144 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100201043; called by muse, varscan2
- RAG1 | c.2615del p.L872* | Frame Shift Del (DEL) | VAF 96/152 reads (63%) | catalogued as rs1195836361; called by pindel, varscan2
- RAI1 | c.4355G>A p.R1452Q | Missense Mutation (SNP) | VAF 76/479 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs368003493; called by muse, mutect2, varscan2
- RASSF6 | c.409G>A p.D137N (on ENST00000342081 / NM_201431.2; = p.D105N on NM_177532.5) | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); catalogued as rs143969358, COSV56716501; called by muse, mutect2, varscan2
- RAVER2 | c.1520C>T p.T507I (on ENST00000294428 / NM_001366165.1; = p.T494I on NM_018211.4) | Missense Mutation (SNP) | VAF 147/327 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs761248241, COSV53805129; called by muse, mutect2, varscan2
- RB1CC1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50276735; called by muse, mutect2, varscan2
- RBBP8NL | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 130/288 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs746142502; called by muse, varscan2
- RBM11 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs763112579, COSV68747915; called by muse, mutect2, varscan2
- RBMS2 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1444248926, COSV56263161; called by muse, mutect2, varscan2
- RCAN3 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV65558129; called by muse, mutect2, varscan2
- RELN | c.8984A>C p.Y2995S | Missense Mutation (SNP) | VAF 107/223 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100635016; called by muse, mutect2, varscan2
- RERG | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375905826, COSV57000887, COSV57001113; called by muse, mutect2, varscan2
- RFPL4A | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 190/579 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs374100254; called by muse, mutect2, varscan2
- RFTN1 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 214/447 reads (48%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV61921480; called by muse, mutect2, varscan2
- RFX3 | c.2137G>C p.E713Q | Missense Mutation (SNP) | VAF 260/261 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); catalogued as COSV101137145; called by muse, mutect2, varscan2
- RHOV | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 120/287 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV55027433; called by muse, mutect2, varscan2
- RILPL2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 89/89 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1022291437; called by muse, mutect2, varscan2
- RIT2 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 93/202 reads (46%) | catalogued as COSV56295413; called by muse, mutect2, varscan2
- RLF | c.4807C>T p.P1603S | Missense Mutation (SNP) | VAF 95/179 reads (53%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV65651464; called by muse, mutect2, varscan2
- RNF152 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 116/250 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV57185219; called by muse, mutect2, varscan2
- RNF213 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 192/427 reads (45%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.446); catalogued as rs760128593; called by muse, mutect2, varscan2
- ROBO1 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458319; called by muse, mutect2, varscan2
- ROS1 | c.6443G>A p.G2148E | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876896, COSV63851575; called by muse, varscan2
- ROS1 | c.4238G>A p.G1413E | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63858077; called by muse, mutect2, varscan2
- RP1 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 183/396 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV55120407; called by muse, mutect2, varscan2
- RP1L1 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 329/691 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.234); catalogued as rs529296323; called by muse, mutect2, varscan2
- RPS19BP1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 197/400 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1326469945; called by muse, mutect2, varscan2
- RUBCN | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.762); catalogued as COSV99065974; called by muse, mutect2, varscan2
- S1PR4 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as rs1484599320; called by muse, mutect2, varscan2
- SAFB2 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 125/313 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV53041958; called by muse, mutect2, varscan2
- SAMD3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs763920331, COSV63717021; called by muse, mutect2
- SAMD7 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 108/225 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs1449477565, COSV100156813; called by muse, mutect2, varscan2
- SATB1 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 127/281 reads (45%) | catalogued as COSV58672438; called by muse, mutect2, varscan2
- SCLT1 | c.1316A>C p.N439T | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.691); catalogued as COSV55406984; called by muse, mutect2, varscan2
- SCN10A | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV71861434; called by muse, varscan2
- SCN1A | c.3439G>A p.E1147K (on ENST00000303395 / NM_001202435.3; = p.E1136K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/315 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.415); catalogued as CM1311660; called by muse, mutect2, varscan2
- SCN3A | c.4550G>A p.G1517E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99325710, COSV99326900; called by muse, mutect2, varscan2
- SCN7A | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.251); catalogued as rs1448558691, COSV69271113; called by muse, mutect2, varscan2
- SDK1 | c.5162C>T p.T1721M | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs542998020, COSV67362658; called by muse, mutect2, varscan2
- SDK1 | c.5656T>C p.Y1886H | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101270057; called by muse, mutect2, varscan2
- SEC14L6 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 115/266 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs760216929; called by muse, mutect2, varscan2
- SEC24C | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1210325582; called by muse, varscan2
- SEMA6D | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV60384559, COSV99054638; called by muse, mutect2
- SEMG2 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV65647848; called by muse, mutect2, varscan2
- SEPTIN12 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs781297591, COSV51615640; called by muse, mutect2, varscan2
- SERPINB4 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV100345837, COSV61984790; called by muse, mutect2, varscan2
- SETBP1 | c.1196A>T p.H399L | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV56335405; called by muse, mutect2, varscan2
- SFMBT2 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs759293227; called by muse, mutect2, varscan2
- SGPL1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV64590985; called by muse, mutect2, varscan2
- SGPL1 | c.1261A>G p.K421E | Missense Mutation (SNP) | VAF 104/206 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs147607292; called by muse, varscan2
- SH2B2 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs782109422; called by muse, mutect2, varscan2
- SHOX2 | c.938C>T p.S313F (on ENST00000441443 / NM_006884.3; = p.S337F on NM_003030.4) | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs149542490, COSV101273767; called by muse, mutect2, varscan2
- SHPK | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 114/236 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs201999400; called by muse, mutect2, varscan2
- SHROOM4 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 164/165 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56789486; called by muse, mutect2, varscan2
- SIGLEC11 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 151/494 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390186020; called by muse, mutect2, varscan2
- SIGLEC12 | c.629G>A p.G210E (on ENST00000291707 / NM_053003.4; = p.G92E on NM_033329.2) | Missense Mutation (SNP) | VAF 142/272 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV52466171; called by muse, mutect2, varscan2
- SIL1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs199921583; called by muse, mutect2, varscan2
- SIM1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 77/134 reads (57%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.073); catalogued as rs367796843, COSV53489580; called by muse, mutect2, varscan2
- SIRT2 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 205/405 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99979157; called by muse, mutect2, varscan2
- SLC12A8 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV58863488; called by muse, mutect2, varscan2
- SLC17A3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV57760736; called by muse, mutect2
- SLC22A25 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as rs781248283; called by muse, mutect2, varscan2
- SLC22A8 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1310792179, COSV100268091; called by muse, mutect2, varscan2
- SLC38A3 | c.1280A>G p.N427S | Missense Mutation (SNP) | VAF 71/71 reads (100%) | SIFT tolerated (0.64); PolyPhen benign (0.044); catalogued as rs767402083; called by muse, mutect2, varscan2
- SLC4A9 | c.2776G>A p.E926K (on ENST00000507527 / NM_001258428.2; = p.E902K on NM_031467.3) | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375734387; called by muse, mutect2, varscan2
- SLC5A8 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867168951, COSV101610512, COSV73310407; called by muse, mutect2, varscan2
- SLC6A1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 245/497 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55113723; called by muse, mutect2, varscan2
- SLC9A8 | c.1385T>G p.L462R | Missense Mutation (SNP) | VAF 140/344 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV64287607; called by muse, mutect2, varscan2
- SLCO1B3 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148029725; called by muse, mutect2, varscan2
- SLCO1B3 | c.1003A>G p.N335D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs758308277; called by muse, mutect2
- SMG6 | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 118/237 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199692074; called by muse, mutect2, varscan2
- SMYD1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101352382; called by muse, mutect2, varscan2
- SNX31 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs765359363, COSV61261774; called by muse, mutect2, varscan2
- SORCS3 | c.1604G>A p.R535K | Missense Mutation (SNP) | VAF 83/155 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1486626651, COSV63810895; called by muse, mutect2, varscan2
- SORL1 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 112/242 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867422963, COSV52757552; called by muse, mutect2, varscan2
- SORL1 | c.3769G>A p.D1257N | Missense Mutation (SNP) | VAF 154/370 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV52748721; called by muse, mutect2
- SP140 | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 114/248 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.568); catalogued as COSV59453655; called by muse, mutect2, varscan2
- SPAG17 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as rs755136638, COSV60463793; called by muse, mutect2, varscan2
- SPAG17 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV60458429; called by muse, mutect2, varscan2
- SPANXD | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 187/195 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV65152280; called by muse, mutect2, varscan2
- SPEF2 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs139870084, COSV56795893; called by muse, mutect2, varscan2
- SPEN | c.6722G>A p.G2241E | Missense Mutation (SNP) | VAF 135/265 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV65364012; called by muse, mutect2, varscan2
- SPICE1 | c.2411G>A p.G804E | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.744); catalogued as rs1416883878; called by muse, varscan2
- SPINK8 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs767643652; called by muse, mutect2, varscan2
- SPIRE2 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 81/81 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs148431869; called by muse, mutect2, varscan2
- SPOCD1 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV57098698; called by muse, mutect2, varscan2
- SPPL2B | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 174/396 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs763351332, COSV71765562; called by muse, mutect2, varscan2
- SPTBN4 | c.7205C>T p.P2402L | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs970550719; called by muse, mutect2, varscan2
- SPTSSB | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0.158); catalogued as COSV63218961; called by muse, mutect2, varscan2
- SRI | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99719739; called by muse, mutect2, varscan2
- SRRM2 | c.3103C>T p.L1035F | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.157); catalogued as rs372711925; called by muse, mutect2, varscan2
- SRRM2 | c.8008C>T p.P2670S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs747113957; called by muse, mutect2, varscan2
- SSBP3 | c.851C>T p.P284L (on ENST00000371320 / NM_145716.4; = p.P264L on NM_018070.5) | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as rs867968219; called by muse, mutect2, varscan2
- SSX1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 144/144 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV65356152; called by muse, mutect2, varscan2
- STAC | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.265); catalogued as rs144484309; called by muse, mutect2, varscan2
- STAC | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs775958676; called by muse, mutect2, varscan2
- STOX1 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53818167; called by muse, mutect2, varscan2
- SUGP1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs1179685803; called by muse, mutect2, varscan2
- SUSD2 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771509280; called by muse, mutect2, varscan2
- SVEP1 | c.5407G>A p.E1803K | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs772505115; called by muse, mutect2, varscan2
- SYCP1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65694118, COSV65698105; called by muse, varscan2
- SYTL3 | c.1320C>A p.Y440* (on ENST00000611299 / NM_001242394.1; = p.Y372* on NM_001009991.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 103/103 reads (100%) | catalogued as COSV51916175; called by muse, mutect2, varscan2
- TAAR5 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs766614989, COSV57799479, COSV57799510; called by muse, mutect2, varscan2
- TADA2B | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as rs765043583; called by muse, mutect2, varscan2
- TAS1R1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV60226895; called by muse, mutect2, varscan2
- TBC1D16 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs757671771; called by muse, mutect2, varscan2
- TCAF1 | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751126928; called by mutect2, varscan2
- TCEA3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.094); catalogued as COSV65840931; called by muse, mutect2, varscan2
- TCHH | c.2882G>T p.R961L | Missense Mutation (SNP) | VAF 142/295 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as COSV104425439; called by muse, mutect2, varscan2
- TCTE1 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 197/422 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs748939646, COSV101025380; called by muse, varscan2
- TDRD5 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 136/292 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1437730414, COSV54249461; called by muse, mutect2, varscan2
- TECTA | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 190/436 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as rs867836820, COSV50691680, COSV50779839; called by muse, mutect2, varscan2
- TEKT4 | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 105/257 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54624529, COSV54625971; called by muse, mutect2, varscan2
- TENM2 | c.2176G>A p.D726N (on ENST00000518659 / NM_001122679.2; = p.D494N on NM_001080428.3) | Missense Mutation (SNP) | VAF 127/127 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs769802847, COSV69122426, COSV69137524; called by muse, mutect2, varscan2
- TENM4 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs767456713; called by muse, mutect2, varscan2
- TENM4 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 206/446 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1390179278; called by muse, mutect2, varscan2
- TEX13C | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 137/137 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1225805497, COSV67111579; called by muse, mutect2, varscan2
- TEX15 | c.3349C>T p.H1117Y (on ENST00000256246; = p.H1500Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.563); catalogued as rs1049652912; called by muse, mutect2, varscan2
- TFCP2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.608); catalogued as rs1393478850; called by muse, mutect2, varscan2
- TFEC | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs753105593, COSV55407446; called by muse, mutect2, varscan2
- TGM1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 206/207 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778635368, CM981914, COSV52863300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THSD7B | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99754968; called by muse, varscan2
- THSD7B | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV55739229; called by muse, varscan2
- TIE1 | c.3007G>A p.G1003R | Missense Mutation (SNP) | VAF 145/311 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV65250685; called by muse, mutect2, varscan2
- TIMM21 | c.364+2T>C p.X122_splice | Splice Site (SNP) | VAF 40/113 reads (35%) | catalogued as rs1271514922; called by muse, mutect2, varscan2
- TLR4 | c.1779G>A p.W593* (on ENST00000355622 / NM_138554.5; = p.W553* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 73/73 reads (100%) | catalogued as rs5030720; called by muse, mutect2, varscan2
- TM6SF1 | c.399G>A p.E133= | Splice Region (SNP) | VAF 45/89 reads (51%) | catalogued as rs1452306728; called by muse, mutect2, varscan2
- TMEM126A | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.65); PolyPhen benign (0.251); catalogued as rs991954040; called by muse, mutect2, varscan2
- TMEM132C | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs868168045; called by muse, mutect2
- TMEM200A | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51657240; called by muse, varscan2
- TMEM207 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs754752355; called by muse, mutect2, varscan2
- TMEM94 | c.3682G>A p.G1228R | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV58595772; called by muse, mutect2, varscan2
- TMPRSS13 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1239296662, COSV70626420; called by muse, mutect2, varscan2
- TMPRSS4 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 128/254 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.722); catalogued as rs200645289; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs748106478, COSV100925350; called by muse, mutect2
- TNPO1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1428903810; called by muse, varscan2
- TNS2 | c.762-5C>T | Splice Region (SNP) | VAF 95/205 reads (46%) | catalogued as rs1431650911; called by muse, mutect2, varscan2
- TNXB | c.9166G>A p.E3056K (on ENST00000647633; = p.E2809K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs1046018971, COSV64477366, COSV64486489, COSV64487656; called by muse, mutect2, varscan2
- TP63 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.885); catalogued as rs754361670, COSV53209193, COSV53218266; called by muse, mutect2, varscan2
- TRANK1 | c.7162C>T p.R2388C | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57159986; called by muse, mutect2, varscan2
- TRAT1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV55469431; called by muse, mutect2, varscan2
- TRDN | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as rs867777177, COSV62116318; called by muse, varscan2
- TREX2 | c.503C>T p.P168L (on ENST00000334497; = p.P125L on NM_080701.3) | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781868111; called by muse, mutect2, varscan2
- TRIM46 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 214/503 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.344); catalogued as rs867177514; called by muse, mutect2, varscan2
- TRIM71 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 101/179 reads (56%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.843); catalogued as rs200204603; called by muse, mutect2, varscan2
- TRPC1 | c.1462G>A p.D488N (on ENST00000476941 / NM_001251845.2; = p.D454N on NM_003304.4) | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV56425128; called by muse, mutect2, varscan2
- TRPV4 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 198/507 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs546287338; called by muse, mutect2, varscan2
- TSC2 | c.2967-8C>T | Splice Region (SNP) | VAF 161/349 reads (46%) | catalogued as rs1060504085; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSSK1B | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as rs868567777; called by muse, mutect2, varscan2
- TTBK2 | c.2974C>T p.L992F | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV51157357; called by muse, mutect2, varscan2
- TTC28 | c.4160C>T p.S1387L | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs1320669216, COSV67413004; called by muse, mutect2, varscan2
- TTN | c.78868G>A p.E26290K (on ENST00000591111; = p.E18866K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | PolyPhen possibly damaging (0.554); catalogued as rs752902445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.75731C>T p.P25244L (on ENST00000591111; = p.P17820L on NM_003319.4) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | PolyPhen benign (0.075); catalogued as rs1208813595, COSV60327695; called by muse, mutect2, varscan2
- TTN | c.69922G>A p.E23308K (on ENST00000591111; = p.E15884K on NM_003319.4) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | PolyPhen possibly damaging (0.654); catalogued as COSV59888493; called by muse, mutect2, varscan2
- TTN | c.67951G>A p.E22651K (on ENST00000591111; = p.E15227K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | PolyPhen benign (0.443); catalogued as rs727505240; ClinVar: uncertain significance; called by muse, varscan2
- TTN | c.28555G>A p.E9519K (on ENST00000591111; = p.E8592K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | PolyPhen probably damaging (0.994); catalogued as COSV60115852; called by muse, mutect2, varscan2
- TTN | c.3285A>C p.E1095D (on ENST00000591111; = p.E1049D on NM_003319.4) | Missense Mutation (SNP) | VAF 226/517 reads (44%) | PolyPhen probably damaging (0.99); catalogued as rs372103803; called by muse, mutect2, varscan2
- UBE3B | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1197725620; called by muse, mutect2, varscan2
- UFL1 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs138835062; called by muse, mutect2, varscan2
- UGT1A6 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 156/348 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as COSV100530011; called by muse, mutect2, varscan2
- UGT1A6 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 157/346 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs116011063, COSV59401146; called by muse, mutect2, varscan2
- UGT2A3 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 105/231 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as rs369449006; called by muse, mutect2, varscan2
- UGT2B7 | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 87/178 reads (49%) | catalogued as rs752860546; called by muse, mutect2, varscan2
- UNC13C | c.5821G>A p.G1941R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs559979535, COSV52858488; called by muse, mutect2, varscan2
- UNC80 | c.7984C>T p.H2662Y | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.979); catalogued as COSV99072500; called by muse, mutect2, varscan2
- USH2A | c.15297+1G>A p.X5099_splice | Splice Site (SNP) | VAF 104/104 reads (100%) | catalogued as rs767630412; called by muse, mutect2, varscan2
- USH2A | c.9154G>A p.E3052K | Missense Mutation (SNP) | VAF 107/107 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.335); catalogued as COSV56382138; called by muse, mutect2, varscan2
- USH2A | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 61/61 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.412); catalogued as COSV56361456, COSV56406558; called by muse, mutect2, varscan2
- USP43 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.561); catalogued as COSV53306037; called by muse, mutect2, varscan2
- VN1R5 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs866515821; called by muse, mutect2, varscan2
1,930 further variants in this file (810 protein-altering or splice-affecting, 784 silent, 336 other) are not listed here.
